Surgical pathology report (de-identified scan), TCGA case TCGA-FF-8043, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site SingHealth, specimen TCGA-FF-8043-01A (Primary Tumor).

Histopathology Report		Biopsy No:	Final
Received Date/Time			Final
Reporting Information	Date/Time : Histopathologist : Laboratory :		Final
Consultant-In-Charge			Final
Submitting Physician			Final
Histopathology Report			Final

DIAGNOSIS

Caecal biopsy:
- Malignant lymphoma, consistent with large B cell lymphoma.

GROSS DESCRIPTION

The specimen is received in formalin, labelled with patient's data, and designated "colonic biopsy". It consists of 3 pieces of tissue measuring 0.2cm to 0.4cm in greatest dimension. (A1{inked blue}; no reserve)

MICROSCOPIC DESCRIPTION

Sections show 3 pieces of colonic mucosa featuring infiltrating sheets of intermediate to large malignant cells, sparing the crypts and causing focal surface erosion.

Immunohistochemical studies done show:

CD 3 Negative
CD 5 Negative
CD 10 Negative
CD 20 Positive
CD 21 Negative
CD 23 Negative
Bcl-2 Positive
Bcl-6 Positive
Cyclin D1 Negative
D2-40 Negative
MUM 1 Positive
MIB-1 High with >80% of lesional cells demonstrating positivity

Pathologist :

Source: NCI Genomic Data Commons file f1d77648-3501-4a54-8187-7f595a16a8fc (TCGA-FF-8043.A6785541-7D40-4A2D-B828-19376217866B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).